Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17R-01A (Primary Tumor).

[page 1 of 3]
103-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium C54.1

Surgical Pathology

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes;
hysterectomy
and bilateral salpingo-oophorectomy: FIGO grade II (of
III)

endometrial adenocarcinoma, endometrioid type, is
identified forming

a mass (4.4 x 3.9 x 1.2 cm), located in the posterior
uterine wall.

The tumor invades 0.1 cm into the myometrium (total wall
thickness

2.2 cm). The tumor does not involve the endocervix or
cervix.

Lymphovascular space invasion is not identified. The
margins are

negative for tumor. The cervix, bilateral ovaries,
fallopian tubes

and appendix are unremarkable. [AJCCpT1bNOMX].

B. Lymph nodes, right pelvic, biopsy: Multiple (5) right
pelvic

lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, biopsy: Multiple (6) left
pelvic

lymph nodes are negative for tumor.

This final pathology report is based on the
gross/macrosopic

examination and frozen section histologic evaluation of
the

specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, bilateral fallopian
tubes and

ovaries" is a 190.0 gram uterus with attached bilateral
tubes and

ovaries and an unremarkable cervix. The uterine serosa is
smooth.

There is a 4.4 x 3.9 x 1.2 cm polypoid mass in the fundus
of the

[page 2 of 3]
endometrial cavity with 2.2 cm myometrial thickness.
There are no
leiomyomas. There is a 3.0 x 2.0 x 1.2 cm right ovary
with a smooth
outer surface and a solid cut surface with a 7.0 x 0.8 cm
right
fallopian tube. There is a 4.2 x 2.8 x 1.7 cm left ovary
with a
ragged outer surface and cystic. There is a solid cut
surface with
a 6.5 x 0.8 cm left fallopian tube. Representative
sections are
submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a
10.0 x
7.0 x 2.0 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a
6.0 x 4.0
x 0.9 cm aggregate of adipose and lymphatic tissue. All
lymphatic
tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, bilateral fallopian tubes and ovaries

- 1 Endometrial mass 1
- 2 Endometrial mass 2
- 3 Endometrial mass 3
- 4 Endometrial mass 4
- 5 Lt tube and ovary
- 6 Rt tube and ovary
- 7 Lower uterine segment
- 8 Cervix 6:00
- 9 Endometrial mass 5

Part B: Right Pelvic Lymph Nodes

- 1 Rt pelvic LNs-1(B1)
- 2 Rt pelvic LNs-1(B2)
- 3 Rt pelvic LNs-1of2(B3)
- 4 Rt pelvic LNs-2of2(B3)
- 5 Rt pelvic LNs-2(B4)

[page 3 of 3]
Part C: Left Pelvic Lymph Nodes

- 1 Lt pelvic LN5 (C1)
- 2 Lt pelvic LN5 (C2)
- 3 Lt pelvic LN2 (C3)
- 4 Lt pelvic LN2 (C4)
- 5 Lt pelvic LN1 (C5)

Source: NCI Genomic Data Commons file 44358fd4-6687-483f-9c67-4a6db1af7540 (TCGA-D1-A17R.51598364-A609-4EBC-8500-53042C9E79E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).